Somatic mutation profile of tumor specimen TCGA-DX-A3UA-01A (aliquot TCGA-DX-A3UA-01A-12D-A307-09) from TCGA case TCGA-DX-A3UA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Short bones of lower limb and associated joints; Age at diagnosis: 47.5 years (17,342 days).
Specimen TCGA-DX-A3UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91713861-365b-4470-8608-181ce8fd0983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UA-10A (Blood Derived Normal), aliquot TCGA-DX-A3UA-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd2511d3-6d5a-4931-a869-f2b09f6e8e60

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRX | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs61748436, CM970396, COSV99704578; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100366708; called by muse, mutect2, varscan2
- CRACR2A | c.677T>G p.I226S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV99365248; called by muse, mutect2, varscan2
- EGF | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs567044142, COSV54475735, COSV54477086; called by muse, mutect2, varscan2
- FAM221A | c.733A>C p.T245P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100794354; called by muse, mutect2, varscan2
- FSIP2 | c.17350G>A p.A5784T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs774274371, COSV58096699; called by muse, mutect2, varscan2
- JAK1 | c.2659G>T p.G887W | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100692069; called by muse, mutect2, varscan2
- KRT77 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100527189; called by muse, mutect2, varscan2
- MET | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.753); catalogued as rs749738523, COSV59263129; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR1L6 | c.896C>T p.P299L (on ENST00000373684; = p.P263L on NM_001004453.2) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464776929, COSV100490948; called by muse, mutect2, varscan2
- PLBD1 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99554665; called by muse, mutect2, varscan2
- PRRC2A | c.5852C>T p.P1951L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV99277321; called by muse, mutect2, varscan2
- RHAG | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV100006702; called by muse, mutect2, varscan2
- ZBED4 | c.2354A>G p.Q785R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99351408; called by muse, mutect2, varscan2
- AKAP9 | c.8189C>T p.A2730V (on ENST00000359028; = p.A2706V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2
- FAT2 | c.9003C>G p.V3001= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV55813179, COSV99943544; called by muse, mutect2, varscan2
- MDGA2 | c.2856T>G p.V952= (on ENST00000399232 / NM_001113498.2; = p.V654= on NM_182830.4) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100637564; called by muse, mutect2, varscan2
- SAR1A | c.171A>G p.L57= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs778910201, COSV100951566; called by muse, mutect2, varscan2
